Somatic mutation profile of tumor specimen 0DWWMS from CCDI case PBCNRU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 9.5 years (3,463 days).
Specimen 0DWWMS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 898994d4-771e-4103-9d46-a5485873da06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWWMA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20e46f60-7cbd-41ce-a3e8-f085f24f7964

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, Silent 2, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RTN4RL1 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58674320; called by muse, mutect2
- TRPV3 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1364988583, COSV100027732; called by muse, mutect2, varscan2
- ALDH1A1 | c.1097C>A p.A366D | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXN1 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 21/693 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- PDIA4 | c.1665G>T p.W555C (on ENST00000286091 / NM_001371244.1; = p.W554C on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RSRC1 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 74/446 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- SIN3A | c.473+1G>A p.X158_splice | Splice Site (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- NLRP10 | c.1200C>T p.G400= | Silent (SNP) | VAF 43/180 reads (24%) | called by muse, mutect2, varscan2
- NOVA2 | c.909C>T p.A303= | Silent (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2, varscan2
- CAPS | c.*44C>G | 3'UTR (SNP) | VAF 3/20 reads (15%) | catalogued as rs1222544947; called by muse, varscan2
- CCDC154 | c.1180-39G>A | Intron (SNP) | VAF 7/39 reads (18%) | catalogued as rs527918221; called by muse, varscan2
- MST1R | c.1231-48G>A | Intron (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
